Somatic mutation profile of tumor specimen TCGA-TQ-A7RO-01A (aliquot TCGA-TQ-A7RO-01A-11D-A33T-08) from TCGA case TCGA-TQ-A7RO, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 29.8 years (10,890 days).
Specimen TCGA-TQ-A7RO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) acc5c6ce-7f7c-4277-be9d-62876cd6df09.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TQ-A7RO-10A (Blood Derived Normal), aliquot TCGA-TQ-A7RO-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c3a8ccf-3c9b-462b-8d6e-4eacc6f5cff2

The open-access MAF lists 21 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Frame Shift Del 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 42/73 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1344635105, COSV50573658; called by muse, mutect2, varscan2
- IDH2 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 45/89 reads (51%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs121913503, COSV57468734, COSV57468971, COSV57472976; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 56/181 reads (31%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AQP10 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs761060478, COSV100269950; called by muse, mutect2, varscan2
- CFAP65 | c.3793G>A p.G1265S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.797); catalogued as rs758180660, COSV100444654, COSV58557449; called by muse, mutect2
- IZUMO1R | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100126808; called by muse, mutect2, varscan2
- MORC2 | c.1670A>G p.Q557R (on ENST00000397641 / NM_001303256.3; = p.Q495R on NM_014941.3) | Missense Mutation (SNP) | VAF 107/273 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as COSV99309495; called by muse, mutect2, varscan2
- PDE4D | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 106/304 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV101550411; called by muse, mutect2, varscan2
- SLC5A11 | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 126/310 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.041); catalogued as rs757763079, COSV61742704; called by muse, mutect2, varscan2
- TRIM23 | c.1306A>G p.I436V | Missense Mutation (SNP) | VAF 73/271 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.74); catalogued as rs1445358636, COSV99139865; called by muse, mutect2, varscan2
- TRPA1 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs755629572, COSV100083259; called by muse, mutect2, varscan2
- TST | c.464C>A p.A155D | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99968153; called by muse, mutect2, varscan2
- WRN | c.1606C>G p.Q536E | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.304); catalogued as rs1060500075, COSV99988328; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITIH4 | c.511del p.H171Tfs*24 | Frame Shift Del (DEL) | VAF 34/113 reads (30%) | called by mutect2, pindel, varscan2
- CATSPERE | c.2232G>A p.R744= | Silent (SNP) | VAF 74/176 reads (42%) | catalogued as COSV100834937; called by muse, mutect2, varscan2
- DISP2 | c.147G>A p.E49= | Silent (SNP) | VAF 62/202 reads (31%) | catalogued as COSV99139723; called by muse, mutect2
- HPX | c.1086G>A p.A362= | Silent (SNP) | VAF 84/196 reads (43%) | catalogued as rs757669613, COSV99793206; called by muse, mutect2, varscan2
- OR9Q1 | c.831C>T p.Y277= | Silent (SNP) | VAF 53/175 reads (30%) | catalogued as COSV100109405; called by muse, mutect2, varscan2
- TLN1 | c.1179C>T p.A393= | Silent (SNP) | VAF 35/180 reads (19%) | catalogued as rs749192861, COSV100147323; called by muse, mutect2, varscan2
- SSPOP | n.4088A>G | RNA (SNP) | VAF 32/98 reads (33%) | catalogued as rs1465993293, COSV100022153; called by muse, mutect2, varscan2
- USH1C | c.1285-7621G>A | Intron (SNP) | VAF 8/37 reads (22%) | catalogued as rs369255684; ClinVar: likely benign; called by muse, mutect2, varscan2
